Surgical pathology report (de-identified scan), TCGA case TCGA-70-6722, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ILSBio, specimen TCGA-70-6722-01A (Primary Tumor).

[page 1 of 5]
Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

GENERAL INFORMATION

Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	Blood Pressure	Heart Rate	

HISTORY OF PRESENT ILLNESS

Chief Complaints: persistent cough, fever; blood in the sputum.

Symptoms: weight loss; tired of eating.

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☒ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
			(yrs)	(yr)
	Alcohol Consumption			
	TYPE	Drinks/day	Duration	When Quit
		(yrs)	(yr)	
Drug Use				
	TYPE	Frequency	Duration	When Quit
			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV			CEA	☐ Negative ☐ Positive: _____		
Hep B			CA 15-3	☐ Negative ☐ Positive: _____		
Hep C			CA 19-9	☐ Negative ☐ Positive: _____		
AFP			PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT	A tumour was found in the lung	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T 3 N 1 M 0	Stage: III A

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Lung Resection (upper right lobe)			
Primary Tumor			
Organ	Detailed Location	Size	
Lung tumor	upper (right)	7 x 6 x 5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T 3 N 1 M 0			Stage: III

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Lung Tumor	7 x 6 x 5 cm	upper right	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Lung Tumor			
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 1 M 0		Stage: III	
Notes: 2 cassettes (nodes) in nitrogen (M1, M2 (positive))			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			X	Streaming			
Mosaic		X		Storiform			
Necrosis		X		Fibrosis			
Lymphocytic Infiltration		X		Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized		X		Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	X		Glandular cell			Round Cell			Large Cell		
Spindle Cell	X		Cell Stratification			Fibroblast			Small Cell		
Keratin	X		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	X		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl	X		Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D₁ 50% . D₂ 20% D₃ 65% D₄ 30%

veerata 20%

2. Cellular Differentiation:

Well	Moderately	Poor
		X

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	X
Nucleolar Prominent				X
Multinucleated Giant Cell				X
Mitotic Activity				X
Nuclear Grade				

Histological Diagnosis: Squamous cell Carcinoma, G3

Comments: M₁, M₂: carcinoma metastasized to LN

Source: NCI Genomic Data Commons file b175669c-61f8-42bd-a0e9-8519761ae544 (TCGA-70-6722.09915CA9-3880-4AA5-AAB2-3762BF1D162C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).